Somatic mutation profile of tumor specimen TCGA-AA-A02O-01A (aliquot TCGA-AA-A02O-01A-21W-A096-10) from TCGA case TCGA-AA-A02O, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Transverse colon; AJCC pathologic stage: Stage II; Age at diagnosis: 82.9 years (30,288 days).
Specimen TCGA-AA-A02O-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0c3296a7-ba22-4f4d-8e5e-7d2da54c1292.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AA-A02O-11A (Solid Tissue Normal), aliquot TCGA-AA-A02O-11A-11W-A096-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/18899f10-0f4a-4607-94db-9c41a127111d

The open-access MAF lists 176 somatic variants for this specimen: 142 protein-altering or splice-affecting, 32 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 124, Silent 32, Frame Shift Del 6, Nonsense Mutation 5, Frame Shift Ins 3, Splice Region 2, 5'UTR 1, RNA 1, In Frame Del 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.3904del p.L1302Cfs*3 | Frame Shift Del (DEL) | VAF 75/129 reads (58%) | catalogued as rs1064794042, COSV57397769; ClinVar: pathogenic; called by mutect2, pindel, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 174/350 reads (50%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 70/209 reads (33%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PPP2R1A | c.773G>A p.R258H | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.375); catalogued as rs863225094, CM157465, COSV59042809; ClinVar: pathogenic; called by muse, mutect2, varscan2
- SMAD4 | c.970T>C p.C324R | Missense Mutation (SNP) | VAF 170/430 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs377767339, CM081440, COSV61691583; ClinVar: uncertain significance / pathogenic; called by muse, varscan2
- ABCA12 | c.4663C>A p.L1555I (on ENST00000272895 / NM_173076.3; = p.L1237I on NM_015657.3) | Missense Mutation (SNP) | VAF 49/142 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs998689781, COSV99792253; called by muse, mutect2, varscan2
- ACSL6 | c.1842G>C p.K614N (on ENST00000379240; = p.K639N on NM_015256.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 267/720 reads (37%) | SIFT tolerated (0.12); PolyPhen benign (0.007); catalogued as COSV99734791; called by muse, mutect2, varscan2
- ACTA1 | c.1018T>C p.S340P | Missense Mutation (SNP) | VAF 3/32 reads (9%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.99); catalogued as COSV100796801; called by muse, mutect2
- ACTL6B | c.467C>T p.A156V | Missense Mutation (SNP) | VAF 58/102 reads (57%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.856); catalogued as rs562984475, COSV50513790, COSV50517182; called by muse, mutect2, varscan2
- ADAM12 | c.2258G>A p.R753H | Missense Mutation (SNP) | VAF 44/114 reads (39%) | SIFT tolerated (0.28); PolyPhen benign (0.001); catalogued as rs199582085; called by muse, mutect2, varscan2
- ADAR | c.640G>A p.D214N | Missense Mutation (SNP) | VAF 47/139 reads (34%) | SIFT tolerated (0.68); PolyPhen benign (0.039); catalogued as COSV52719204; called by muse, mutect2, varscan2
- ADD2 | c.14C>T p.T5M | Missense Mutation (SNP) | VAF 19/35 reads (54%) | SIFT deleterious (0); PolyPhen benign (0.179); catalogued as rs782403508, COSV52459544; called by muse, mutect2, varscan2
- ADNP2 | c.2111C>T p.P704L | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1476275568, COSV51536545; called by muse, mutect2, varscan2
- ADRB3 | c.241G>A p.A81T | Missense Mutation (SNP) | VAF 14/22 reads (64%) | SIFT tolerated (0.25); PolyPhen benign (0.009); catalogued as rs201912869, COSV61461960, COSV61462421; called by muse, varscan2
- AFF3 | c.2792C>T p.T931M | Missense Mutation (SNP) | VAF 51/129 reads (40%) | SIFT deleterious (0.05); PolyPhen benign (0.039); catalogued as rs373018231; called by muse, mutect2, varscan2
- ANK2 | c.9490G>T p.E3164* | Nonsense Mutation (SNP) | VAF 24/80 reads (30%) | catalogued as COSV100004499; called by muse, mutect2, varscan2
- B9D1 | c.109G>A p.G37S | Missense Mutation (SNP) | VAF 31/39 reads (79%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.641); catalogued as rs771997194, COSV52069908; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- BPIFB2 | c.19C>A p.L7M | Missense Mutation (SNP) | VAF 19/36 reads (53%) | SIFT tolerated, low confidence (0.08); PolyPhen possibly damaging (0.784); catalogued as COSV50068710, COSV50072000; called by muse, mutect2, varscan2
- C22orf42 | c.346G>T p.V116L | Missense Mutation (SNP) | VAF 49/148 reads (33%) | SIFT tolerated, low confidence (0.57); PolyPhen benign (0.198); catalogued as COSV66076452; called by muse, mutect2, varscan2
- CACNG5 | c.361G>A p.G121R | Missense Mutation (SNP) | VAF 223/901 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs201783473; called by muse, mutect2, varscan2
- CELSR1 | c.4055C>T p.P1352L | Missense Mutation (SNP) | VAF 11/25 reads (44%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as rs772065518, COSV53096509; called by muse, varscan2
- CENPF | c.3298A>G p.M1100V | Missense Mutation (SNP) | VAF 67/186 reads (36%) | SIFT tolerated (0.82); PolyPhen benign (0); catalogued as COSV100872043; called by muse, mutect2, varscan2
- CHL1 | c.203C>T p.S68L | Missense Mutation (SNP) | VAF 63/313 reads (20%) | SIFT tolerated (0.14); PolyPhen benign (0.017); catalogued as rs1159504136, COSV56587630; called by muse, mutect2, varscan2
- CLU | c.236A>T p.K79M | Missense Mutation (SNP) | VAF 158/295 reads (54%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.995); catalogued as COSV100324460; called by muse, mutect2, varscan2
- COL12A1 | c.5978G>A p.R1993Q | Missense Mutation (SNP) | VAF 96/214 reads (45%) | SIFT tolerated (0.53); PolyPhen benign (0); catalogued as rs748657616, COSV100486657; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- COL12A1 | c.4900G>A p.V1634I | Missense Mutation (SNP) | VAF 246/623 reads (39%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.776); catalogued as rs772992461, COSV100486153; called by muse, mutect2, varscan2
- CYP1A1 | c.234T>G p.I78M | Missense Mutation (SNP) | VAF 17/44 reads (39%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.961); catalogued as COSV101122385; called by muse, mutect2, varscan2
- DELE1 | c.1249G>A p.A417T | Missense Mutation (SNP) | VAF 83/184 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs137962377, COSV52004785; called by muse, mutect2, varscan2
- DNAH9 | c.4923C>A p.F1641L | Missense Mutation (SNP) | VAF 159/202 reads (79%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.539); catalogued as COSV52367074, COSV52378981; called by muse, mutect2, varscan2
- EFNB3 | c.197G>A p.R66Q | Missense Mutation (SNP) | VAF 19/24 reads (79%) | SIFT tolerated (0.16); PolyPhen benign (0.06); catalogued as rs370940378; called by muse, mutect2, varscan2
- EIF4E2 | c.104G>A p.R35Q | Missense Mutation (SNP) | VAF 130/364 reads (36%) | SIFT tolerated (0.57); PolyPhen benign (0.001); catalogued as rs149079029; called by muse, varscan2
- ETS2 | c.825C>A p.D275E | Missense Mutation (SNP) | VAF 33/103 reads (32%) | SIFT tolerated (0.79); PolyPhen benign (0); catalogued as COSV62873860; called by muse, mutect2, varscan2
- EVL | c.245G>T p.R82L (on ENST00000402714 / NM_001330221.2; = p.R84L on NM_016337.3) | Missense Mutation (SNP) | VAF 45/163 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as COSV67376680; called by muse, mutect2, varscan2
- F11 | c.564T>G p.F188L | Missense Mutation (SNP) | VAF 89/246 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53008707; called by muse, mutect2, varscan2
- FAT4 | c.9680C>G p.T3227R | Missense Mutation (SNP) | VAF 31/75 reads (41%) | SIFT tolerated (0.13); PolyPhen benign (0.224); catalogued as COSV100630410; called by muse, mutect2, varscan2
- FBXL7 | c.925G>A p.V309I | Missense Mutation (SNP) | VAF 17/61 reads (28%) | SIFT tolerated (0.68); PolyPhen benign (0.003); catalogued as rs750820412, COSV61643759; called by muse, mutect2, varscan2
- FEM1A | c.1732G>A p.D578N | Missense Mutation (SNP) | VAF 35/68 reads (51%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.914); catalogued as COSV54164581; called by muse, mutect2, varscan2
- FMR1NB | c.704G>A p.R235Q | Missense Mutation (SNP) | VAF 108/258 reads (42%) | SIFT tolerated (0.44); PolyPhen benign (0.007); catalogued as rs868988926, COSV65071402; called by muse, mutect2, varscan2
- FREM2 | c.1216C>T p.R406C | Missense Mutation (SNP) | VAF 37/108 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs1332308902, COSV54839208; called by muse, mutect2, varscan2
- FRY | c.833G>A p.R278Q | Missense Mutation (SNP) | VAF 122/326 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.918); catalogued as COSV66565996, COSV66574191; called by muse, mutect2, varscan2
- GABRR2 | c.1069C>T p.R357W | Missense Mutation (SNP) | VAF 33/84 reads (39%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.997); catalogued as rs779408316, COSV101299051; called by muse, mutect2, varscan2
- GAS2L3 | c.1112C>T p.S371F | Missense Mutation (SNP) | VAF 36/179 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.671); catalogued as COSV57158509; called by muse, mutect2, varscan2
- GRIK3 | c.1348C>T p.R450W | Missense Mutation (SNP) | VAF 20/44 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.894); catalogued as COSV66136268; called by muse, mutect2, varscan2
- GRM3 | c.1393C>T p.R465* | Nonsense Mutation (SNP) | VAF 124/264 reads (47%) | catalogued as rs891435292, COSV64467524; called by muse, mutect2, varscan2
- H2BC4 | c.310C>T p.P104S | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); catalogued as COSV58417118; called by muse, mutect2
- HAO1 | c.514C>T p.R172C | Missense Mutation (SNP) | VAF 87/303 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); catalogued as rs778551661, COSV101113118, COSV99060338; called by muse, mutect2, varscan2
- HAPLN4 | c.292G>A p.V98I | Missense Mutation (SNP) | VAF 7/21 reads (33%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.895); catalogued as COSV52270585; called by muse, mutect2, varscan2
- HFM1 | c.4200dup p.I1401Yfs*2 | Frame Shift Ins (INS) | VAF 43/150 reads (29%) | catalogued as rs766204131; called by mutect2, varscan2
- HIPK2 | c.2522G>A p.R841H | Missense Mutation (SNP) | VAF 40/76 reads (53%) | SIFT tolerated (0.24); PolyPhen probably damaging (0.976); catalogued as rs374263328; called by muse, mutect2, varscan2
- HS3ST4 | c.1255C>T p.R419C | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as COSV100503232; called by muse, mutect2
- HTT | c.8995G>A p.G2999R | Missense Mutation (SNP) | VAF 16/52 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs752320329, COSV100750514, COSV100751316; called by muse, mutect2, varscan2
- IBSP | c.15A>C p.L5F | Missense Mutation (SNP) | VAF 91/227 reads (40%) | SIFT tolerated (0.12); PolyPhen benign (0.012); catalogued as COSV56896773; called by muse, mutect2, varscan2
- IFT80 | c.1643C>T p.T548I | Missense Mutation (SNP) | VAF 76/281 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.503); catalogued as COSV100424456; called by muse, mutect2, varscan2
- IGSF21 | c.1139G>A p.R380Q | Missense Mutation (SNP) | VAF 25/54 reads (46%) | SIFT deleterious (0.03); PolyPhen benign (0.033); catalogued as rs201284891, COSV52124955, COSV99246413; called by muse, mutect2, varscan2
- IL18R1 | c.523G>A p.A175T | Missense Mutation (SNP) | VAF 67/194 reads (35%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.99); catalogued as rs776875280, COSV99295349; called by muse, mutect2, varscan2
- KCNA1 | c.205C>T p.R69C | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66838319; called by muse, mutect2, varscan2
- KCNH1 | c.2762C>T p.T921M (on ENST00000271751 / NM_172362.3; = p.T894M on NM_002238.4) | Missense Mutation (SNP) | VAF 31/88 reads (35%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.34); catalogued as rs768501927, COSV55095216; called by muse, mutect2, varscan2
- KCTD13 | c.412C>T p.Q138* | Nonsense Mutation (SNP) | VAF 45/55 reads (82%) | catalogued as COSV58161129; called by muse, mutect2, varscan2
- KDM6B | c.4522G>A p.V1508I | Missense Mutation (SNP) | VAF 32/45 reads (71%) | SIFT deleterious (0.01); PolyPhen benign (0.124); catalogued as COSV99640802; called by muse, mutect2, varscan2
- KIF13A | c.4792G>T p.G1598C | Missense Mutation (SNP) | VAF 60/163 reads (37%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99438417; called by muse, mutect2, varscan2
- KRIT1 | c.146G>A p.R49K | Missense Mutation (SNP) | VAF 269/501 reads (54%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.867); catalogued as COSV100388961; called by mutect2, varscan2
- LARP4B | c.703C>T p.R235C | Missense Mutation (SNP) | VAF 213/661 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1381139107, COSV60222919; called by muse, mutect2, varscan2
- LINGO1 | c.328G>A p.V110M | Missense Mutation (SNP) | VAF 11/42 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.422); catalogued as COSV100796500, COSV62438032; called by muse, mutect2, varscan2
- LRBA | c.3016A>T p.N1006Y | Missense Mutation (SNP) | VAF 220/561 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.172); catalogued as COSV100842126; called by muse, mutect2, varscan2
- LRP2 | c.3265C>T p.R1089C | Missense Mutation (SNP) | VAF 114/276 reads (41%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.601); catalogued as rs763860226, COSV55542058; called by muse, mutect2, varscan2
- MAB21L2 | c.620G>T p.G207V | Missense Mutation (SNP) | VAF 10/16 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100462464; called by muse, mutect2, varscan2
- MACROD2 | c.14A>G p.N5S | Missense Mutation (SNP) | VAF 108/202 reads (53%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.632); catalogued as COSV54027709; called by muse, mutect2, varscan2
- NCOA5 | c.1004G>A p.R335H | Missense Mutation (SNP) | VAF 70/264 reads (27%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs35315891; called by muse, mutect2, varscan2
- NKX3-1 | c.526C>T p.R176C | Missense Mutation (SNP) | VAF 94/395 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV66512049; called by muse, mutect2, varscan2
- NLRP5 | c.792A>T p.Q264H | Missense Mutation (SNP) | VAF 82/154 reads (53%) | SIFT tolerated (0.31); PolyPhen benign (0.006); catalogued as COSV66766513; called by muse, mutect2, varscan2
- NPY2R | c.186G>T p.L62F | Missense Mutation (SNP) | VAF 135/548 reads (25%) | SIFT tolerated (0.06); PolyPhen benign (0.07); catalogued as COSV61529132; called by muse, mutect2, varscan2
- NR1D1 | c.260C>T p.S87L | Missense Mutation (SNP) | VAF 26/44 reads (59%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as rs751801001, COSV52845241; called by muse, mutect2, varscan2
- NRG1 | c.399C>T p.N133= | Splice Region (SNP) | VAF 99/464 reads (21%) | catalogued as rs374418193, COSV55171785; called by muse, mutect2, varscan2
- NUBP1 | c.748G>A p.G250R | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs267604406, COSV51595010; called by muse, mutect2, varscan2
- NYAP2 | c.1318G>A p.V440I | Missense Mutation (SNP) | VAF 16/35 reads (46%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.991); catalogued as rs551391208, COSV56003545; called by muse, mutect2, varscan2
- OBSCN | c.9407G>A p.R3136Q | Missense Mutation (SNP) | VAF 11/27 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.19); catalogued as rs754103170, COSV52844717; called by muse, mutect2, varscan2
- OPRM1 | c.979G>C p.G327R | Missense Mutation (SNP) | VAF 97/202 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100002575; called by muse, mutect2, varscan2
- OR1K1 | c.821T>G p.V274G | Missense Mutation (SNP) | VAF 27/59 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99474383; called by muse, mutect2, varscan2
- OR2M4 | c.877C>T p.R293C | Missense Mutation (SNP) | VAF 50/149 reads (34%) | SIFT tolerated (0.05); PolyPhen benign (0.033); catalogued as rs531102387, COSV60708785, COSV60708977; called by muse, mutect2, varscan2
- OR52N4 | c.635A>G p.D212G | Missense Mutation (SNP) | VAF 294/757 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV57891928; called by muse, mutect2, varscan2
- OR5AS1 | c.937G>A p.E313K | Missense Mutation (SNP) | VAF 33/109 reads (30%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100546256, COSV57983892; called by muse, mutect2, varscan2
- OR6K3 | c.823T>G p.L275V (on ENST00000368146; = p.L259V on NM_001005327.2) | Missense Mutation (SNP) | VAF 98/276 reads (36%) | SIFT tolerated (0.93); PolyPhen probably damaging (0.993); catalogued as COSV63745754, COSV63746082; called by muse, mutect2, varscan2
- OR7A10 | c.604G>T p.A202S | Missense Mutation (SNP) | VAF 18/77 reads (23%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.062); catalogued as COSV50166652; called by muse, mutect2, varscan2
- PAPPA | c.2849G>A p.G950D | Missense Mutation (SNP) | VAF 75/180 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60290310; called by muse, mutect2, varscan2
- PCDH11Y | c.3443C>T p.P1148L | Missense Mutation (SNP) | VAF 221/267 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs374229187, COSV53087801; called by muse, mutect2, varscan2
- PCDHA6 | c.2003C>T p.S668L | Missense Mutation (SNP) | VAF 6/11 reads (55%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.072); catalogued as COSV65346358; called by muse, mutect2
- PDE6A | c.1049T>C p.V350A | Missense Mutation (SNP) | VAF 201/248 reads (81%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.803); catalogued as COSV54930130, COSV99678163; called by muse, mutect2, varscan2
- PEG3 | c.1652G>T p.S551I | Missense Mutation (SNP) | VAF 51/176 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55642707; called by muse, mutect2, varscan2
- PHF24 | c.104G>A p.R35Q | Missense Mutation (SNP) | VAF 41/114 reads (36%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.585); catalogued as rs894237442, COSV99646319; called by muse, mutect2, varscan2
- PLOD3 | c.1005C>T p.N335= | Splice Region (SNP) | VAF 13/69 reads (19%) | catalogued as rs763712959, COSV56185057, COSV56186471; called by muse, mutect2, varscan2
- POLI | c.493C>G p.L165V | Missense Mutation (SNP) | VAF 309/571 reads (54%) | SIFT tolerated (0.07); PolyPhen benign (0.392); catalogued as rs745954398, COSV54190980; called by muse, mutect2, varscan2
- PPEF2 | c.1113G>T p.R371S | Missense Mutation (SNP) | VAF 17/57 reads (30%) | SIFT tolerated (0.26); PolyPhen benign (0.272); catalogued as COSV54425078; called by muse, mutect2, varscan2
- PPP1R16B | c.1436C>T p.T479M | Missense Mutation (SNP) | VAF 16/26 reads (62%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs201345539, COSV55381861; called by muse, mutect2, varscan2
- PRTG | c.3167del p.F1056Sfs*30 | Frame Shift Del (DEL) | VAF 34/90 reads (38%) | catalogued as rs768325902, COSV101221331; called by mutect2, varscan2
- PSG7 | c.471C>A p.N157K | Missense Mutation (SNP) | VAF 115/445 reads (26%) | SIFT tolerated (0.09); PolyPhen benign (0.037); catalogued as rs1339622711, COSV101343350; called by muse, mutect2, varscan2
- PSME4 | c.3943G>C p.D1315H | Missense Mutation (SNP) | VAF 59/159 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.479); catalogued as COSV101122702; called by muse, mutect2, varscan2
- RANBP3 | c.343T>C p.Y115H | Missense Mutation (SNP) | VAF 313/548 reads (57%) | SIFT tolerated, low confidence (0.12); PolyPhen possibly damaging (0.713); catalogued as COSV99222536; called by muse, mutect2, varscan2
- RIPOR1 | c.3554G>A p.R1185Q (on ENST00000379312 / NM_001193522.2; = p.R1181Q on NM_024519.4) | Missense Mutation (SNP) | VAF 14/43 reads (33%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.913); catalogued as rs757360604, COSV99243771; called by muse, mutect2, varscan2
- ROBO1 | c.3868G>A p.D1290N | Missense Mutation (SNP) | VAF 90/212 reads (42%) | SIFT tolerated (0.32); PolyPhen benign (0.075); catalogued as rs761586528, COSV71392657; called by muse, mutect2, varscan2
- RORB | c.869G>A p.R290Q (on ENST00000396204 / NM_001365023.1; = p.R279Q on NM_006914.4) | Missense Mutation (SNP) | VAF 126/309 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as rs770337953, COSV65338712; called by muse, mutect2, varscan2
- RSPO3 | c.577A>G p.T193A | Missense Mutation (SNP) | VAF 90/213 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.142); catalogued as rs1393662886, COSV63152306; called by muse, mutect2, varscan2
- RYR3 | c.1601A>C p.N534T | Missense Mutation (SNP) | VAF 135/321 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101214827; called by muse, mutect2, varscan2
- SCN8A | c.5795G>A p.R1932Q | Missense Mutation (SNP) | VAF 23/125 reads (18%) | SIFT tolerated (0.32); PolyPhen benign (0.001); catalogued as rs371766742; called by muse, mutect2, varscan2
- SDK1 | c.3542C>T p.T1181M | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.949); catalogued as rs1438033324, COSV67357293; called by muse, mutect2, varscan2
- SEPTIN2 | c.286C>T p.R96C | Missense Mutation (SNP) | VAF 100/219 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV63472424; called by muse, mutect2, varscan2
- SETX | c.7121_7122del p.V2374Gfs*20 | Frame Shift Del (DEL) | VAF 128/422 reads (30%) | catalogued as rs765371601; called by pindel, varscan2
- SLC12A9 | c.790G>A p.V264M | Missense Mutation (SNP) | VAF 22/150 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as rs373781782; called by muse, mutect2, varscan2
- SLC24A4 | c.1435G>A p.G479R | Missense Mutation (SNP) | VAF 166/317 reads (52%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1171307519, COSV54118684; called by muse, mutect2, varscan2
- SMC1B | c.1254+1G>T p.X418_splice | Splice Site (SNP) | VAF 156/408 reads (38%) | catalogued as COSV62532369; called by muse, mutect2, varscan2
- SOD2 | c.367C>T p.R123C | Missense Mutation (SNP) | VAF 89/211 reads (42%) | SIFT deleterious (0); PolyPhen benign (0.021); catalogued as rs143582231; called by muse, mutect2, varscan2
- SPDYE3 | c.1324C>T p.R442C | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.593); catalogued as rs775869494, COSV60107937; called by mutect2, varscan2
- SSX5 | c.215G>A p.R72H (on ENST00000347757 / NM_175723.1; = p.R113H on NM_021015.4) | Missense Mutation (SNP) | VAF 242/279 reads (87%) | SIFT tolerated (0.6); PolyPhen benign (0.003); catalogued as rs149409740, COSV61255238; called by muse, mutect2, varscan2
- STC1 | c.280G>C p.E94Q | Missense Mutation (SNP) | VAF 84/283 reads (30%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.927); catalogued as COSV51689426; called by muse, mutect2, varscan2
- SULT4A1 | c.775G>A p.V259I | Missense Mutation (SNP) | VAF 73/206 reads (35%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.772); catalogued as rs374057069, COSV50782525; called by muse, mutect2, varscan2
- TCERG1L | c.1177G>C p.E393Q | Missense Mutation (SNP) | VAF 46/128 reads (36%) | SIFT deleterious (0.01); PolyPhen benign (0.284); catalogued as COSV64054339; called by muse, mutect2, varscan2
- TENM3 | c.3232G>T p.V1078F | Missense Mutation (SNP) | VAF 120/304 reads (39%) | SIFT tolerated (0.41); PolyPhen probably damaging (0.987); catalogued as COSV101305498; called by muse, mutect2, varscan2
- TEX14 | c.2836G>T p.A946S (on ENST00000240361 / NM_001201457.2; = p.A940S on NM_031272.5) | Missense Mutation (SNP) | VAF 64/445 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV99543778; called by muse, mutect2, varscan2
- TLN1 | c.1082C>T p.A361V | Missense Mutation (SNP) | VAF 93/215 reads (43%) | SIFT deleterious (0); PolyPhen possibly damaging (0.667); catalogued as COSV59207697; called by muse, mutect2, varscan2
- TMEM132A | c.2732G>A p.R911Q (on ENST00000453848 / NM_178031.3; = p.R912Q on NM_017870.4) | Missense Mutation (SNP) | VAF 9/15 reads (60%) | SIFT tolerated (0.23); PolyPhen benign (0.024); catalogued as rs142666359; called by muse, mutect2, varscan2
- TRPA1 | c.271C>A p.L91M | Missense Mutation (SNP) | VAF 150/525 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as rs1231313071, COSV100085330; called by muse, mutect2, varscan2
- TRPC7 | c.466G>A p.E156K | Missense Mutation (SNP) | VAF 41/90 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.246); catalogued as COSV61454184; called by muse, mutect2, varscan2
- TSHZ3 | c.2284G>T p.A762S | Missense Mutation (SNP) | VAF 57/121 reads (47%) | SIFT tolerated (0.11); PolyPhen benign (0.378); catalogued as COSV99078516; called by muse, mutect2, varscan2
- TTC37 | c.3788C>T p.A1263V | Missense Mutation (SNP) | VAF 132/470 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1057014596, COSV100706931; called by muse, mutect2, varscan2
- TTLL8 | c.625C>T p.R209W | Missense Mutation (SNP) | VAF 14/38 reads (37%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.65); catalogued as rs748454999, COSV56724210; called by muse, mutect2, varscan2
- TTN | c.95407A>G p.T31803A (on ENST00000591111; = p.T24379A on NM_003319.4) | Missense Mutation (SNP) | VAF 62/156 reads (40%) | PolyPhen possibly damaging (0.741); catalogued as COSV100632686; called by muse, mutect2, varscan2
- TUSC3 | c.1001G>A p.R334H | Missense Mutation (SNP) | VAF 312/1316 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs748401651, COSV65885423; called by muse, mutect2, varscan2
- UBXN7 | c.951A>C p.E317D | Missense Mutation (SNP) | VAF 76/219 reads (35%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV99581838; called by muse, mutect2, varscan2
- UGT2B10 | c.773G>C p.R258P | Missense Mutation (SNP) | VAF 30/442 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV55322438; called by muse, mutect2
- VAV1 | c.1363C>T p.R455W | Missense Mutation (SNP) | VAF 228/400 reads (57%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV100409515; called by muse, mutect2, varscan2
- XKR6 | c.803G>A p.R268Q | Missense Mutation (SNP) | VAF 68/116 reads (59%) | SIFT tolerated (0.49); PolyPhen probably damaging (0.914); catalogued as rs758968294, COSV100441169; called by muse, mutect2, varscan2
- ZEB1 | c.1199del p.G400Vfs*6 | Frame Shift Del (DEL) | VAF 111/308 reads (36%) | catalogued as COSV58036985; called by mutect2, pindel, varscan2
- ZNF320 | c.567C>A p.Y189* | Nonsense Mutation (SNP) | VAF 58/254 reads (23%) | catalogued as COSV67088667; called by muse, mutect2, varscan2
- ZNF654 | c.2122G>C p.G708R | Missense Mutation (SNP) | VAF 24/274 reads (9%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.599); catalogued as COSV58806863; called by muse, mutect2
- ZNF91 | c.3566T>G p.L1189R | Missense Mutation (SNP) | VAF 6/50 reads (12%) | PolyPhen possibly damaging (0.756); catalogued as rs967383794, COSV56086544; called by muse, mutect2, varscan2
- ZPBP | c.434A>T p.K145I | Missense Mutation (SNP) | VAF 211/870 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as COSV50430595; called by muse, mutect2, varscan2
- ZSCAN31 | c.298C>T p.R100W | Missense Mutation (SNP) | VAF 52/119 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.003); catalogued as rs768839187, COSV60180747; called by muse, mutect2, varscan2
- ADNP | c.3032dup p.A1012Sfs*11 | Frame Shift Ins (INS) | VAF 25/116 reads (22%) | called by mutect2, pindel, varscan2
- FSD1 | c.1260_1263delinsTG p.C421Afs*6 | Frame Shift Del (DEL) | VAF 16/79 reads (20%) | called by pindel, varscan2*
- MTCL1 | c.5572del p.L1858Wfs*5 (on ENST00000306329 / NM_001378206.1; = p.L1539Wfs*5 on NM_015210.4) | Frame Shift Del (DEL) | VAF 8/33 reads (24%) | called by mutect2, pindel, varscan2
- PRF1 | c.1411_1416del p.L471_L472del | In Frame Del (DEL) | VAF 33/103 reads (32%) | called by mutect2, pindel, varscan2
- SPEG | c.8195dup p.Y2732* | Nonsense Mutation (INS) | VAF 6/26 reads (23%) | called by mutect2, pindel, varscan2
- WDR11 | c.2928dup p.Q977Sfs*9 | Frame Shift Ins (INS) | VAF 20/88 reads (23%) | called by mutect2, pindel, varscan2
- ANO5 | c.1752C>A p.G584= | Silent (SNP) | VAF 123/336 reads (37%) | catalogued as COSV61088618; called by muse, mutect2, varscan2
- ANO7 | c.1221C>T p.S407= (on ENST00000274979; = p.S353= on NM_001370694.2) | Silent (SNP) | VAF 26/53 reads (49%) | catalogued as rs140168050; called by muse, mutect2, varscan2
- ATP4A | c.1323C>T p.R441= | Silent (SNP) | VAF 16/45 reads (36%) | catalogued as COSV52868521; called by muse, mutect2, varscan2
- CACNA1A | c.5511C>T p.Y1837= | Silent (SNP) | VAF 59/203 reads (29%) | catalogued as rs777510892, COSV64207391; called by muse, mutect2, varscan2
- CTNND2 | c.1281C>T p.R427= | Silent (SNP) | VAF 39/116 reads (34%) | catalogued as rs1269981475, COSV58912343, COSV58936105; called by muse, mutect2, varscan2
- DCAF4L2 | c.846C>A p.G282= | Silent (SNP) | VAF 114/233 reads (49%) | catalogued as COSV60481024; called by muse, mutect2, varscan2
- DCAF4L2 | c.483G>A p.A161= | Silent (SNP) | VAF 82/159 reads (52%) | catalogued as rs1369010251, COSV60480151; called by muse, mutect2, varscan2
- DOK6 | c.384C>T p.A128= | Silent (SNP) | VAF 78/139 reads (56%) | catalogued as rs773183518, COSV66935398; called by muse, mutect2
- GORASP1 | c.477G>A p.K159= | Silent (SNP) | VAF 34/97 reads (35%) | catalogued as COSV56533521; called by muse, mutect2, varscan2
- GRIK2 | c.1644A>G p.T548= | Silent (SNP) | VAF 99/255 reads (39%) | catalogued as COSV59758375; called by muse, mutect2, varscan2
- GTF3C3 | c.72G>T p.R24= | Silent (SNP) | VAF 146/354 reads (41%) | catalogued as COSV55833795; called by muse, mutect2, varscan2
- GUCY2D | c.1191C>T p.D397= | Silent (SNP) | VAF 10/29 reads (34%) | catalogued as rs756210907, COSV54697853; called by muse, mutect2, varscan2
- HK1 | c.837G>A p.R279= | Silent (SNP) | VAF 61/196 reads (31%) | catalogued as COSV53863671; called by muse, mutect2, varscan2
- HYDIN | c.11740T>C p.L3914= | Silent (SNP) | VAF 97/137 reads (71%) | catalogued as COSV101125237; called by muse, mutect2, varscan2
- JHY | c.936C>T p.I312= | Silent (SNP) | VAF 106/281 reads (38%) | catalogued as rs142483643; called by muse, mutect2, varscan2
- KIF1A | c.4995C>T p.S1665= (on ENST00000320389 / NM_001379639.1; = p.S1657= on NM_004321.8 and 5 other RefSeq transcripts) | Silent (SNP) | VAF 4/12 reads (33%) | catalogued as rs899778611, COSV57497130; called by muse, varscan2
- MATN3 | c.765C>A p.S255= | Silent (SNP) | VAF 4/52 reads (8%) | catalogued as COSV101337481, COSV101337486; called by muse, mutect2
- MYH9 | c.5559C>T p.D1853= | Silent (SNP) | VAF 80/190 reads (42%) | catalogued as rs775990931, COSV53391158; called by muse, mutect2, varscan2
- NCAPH | c.711G>A p.R237= | Silent (SNP) | VAF 63/160 reads (39%) | catalogued as COSV53637800; called by muse, mutect2, varscan2
- NCBP3 | c.981G>A p.S327= | Silent (SNP) | VAF 88/248 reads (35%) | catalogued as rs749386187, COSV50109359; called by muse, mutect2, varscan2
- OR5AC2 | c.426C>G p.L142= | Silent (SNP) | VAF 77/229 reads (34%) | catalogued as rs761041692, COSV62279933; called by muse, mutect2, varscan2
- OTOGL | c.6729C>T p.C2243= (on ENST00000547103; = p.C2234= on NM_173591.4 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 46/156 reads (29%) | catalogued as COSV54021047; called by muse, mutect2, varscan2
- PCDHA7 | c.1974G>A p.S658= | Silent (SNP) | VAF 8/26 reads (31%) | catalogued as COSV65336376; called by muse, mutect2, varscan2
- PKN3 | c.1797C>T p.D599= | Silent (SNP) | VAF 9/23 reads (39%) | catalogued as rs1233666244, COSV52578668; called by muse, mutect2, varscan2
- PPP3R2 | c.327C>T p.N109= | Silent (SNP) | VAF 11/153 reads (7%) | catalogued as COSV62450353; called by muse, mutect2
- PRLR | c.37C>T p.L13= | Silent (SNP) | VAF 164/454 reads (36%) | catalogued as rs775568148, COSV51498713; called by muse, mutect2, varscan2
- SEL1L2 | c.681G>A p.S227= | Silent (SNP) | VAF 30/512 reads (6%) | catalogued as rs755645284, COSV53155257; called by muse, mutect2
- SLFN11 | c.891C>A p.L297= | Silent (SNP) | VAF 103/919 reads (11%) | catalogued as COSV100390779, COSV57699959; called by muse, mutect2, varscan2
- SRP72 | c.1761G>A p.R587= | Silent (SNP) | VAF 49/127 reads (39%) | catalogued as COSV100714389; called by muse, mutect2, varscan2
- TAS1R2 | c.924G>A p.P308= | Silent (SNP) | VAF 26/81 reads (32%) | catalogued as rs1399645112, COSV64746444; called by muse, mutect2, varscan2
- WDR90 | c.5016G>A p.K1672= | Silent (SNP) | VAF 19/22 reads (86%) | catalogued as rs1385667144, COSV53473578; called by muse, mutect2, varscan2
- ZBTB46 | c.462G>A p.T154= | Silent (SNP) | VAF 14/21 reads (67%) | catalogued as rs573566471, COSV55513131; called by muse, mutect2, varscan2
- BTN2A3P | n.824G>A | RNA (SNP) | VAF 30/76 reads (39%) | catalogued as rs780533444; called by muse, mutect2, varscan2
- CCDC112 | c.-97T>C | 5'UTR (SNP) | VAF 123/276 reads (45%) | catalogued as COSV65473721; called by muse, mutect2, varscan2
